Somatic mutation profile of tumor specimen TCGA-BJ-A0Z3-01A (aliquot TCGA-BJ-A0Z3-01A-11D-A13W-08) from TCGA case TCGA-BJ-A0Z3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.7 years (12,295 days).
Specimen TCGA-BJ-A0Z3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d5aa72f-5cfc-4c47-8daa-b1d9893ac651.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0Z3-10A (Blood Derived Normal), aliquot TCGA-BJ-A0Z3-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5092e0f0-ffcc-4de7-ad4e-85a4737d81e0

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNB1 | c.2230C>A p.P744T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV62700183; called by muse, mutect2
- KLHL40 | c.467T>A p.I156N | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55134570; called by muse, mutect2
- RASSF1 | c.941G>A p.R314Q (on ENST00000357043 / NM_170714.2; = p.R310Q on NM_007182.5) | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142957899, COSV51701782; called by muse, varscan2
- RFPL1 | c.242G>C p.C81S | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs369425454, COSV62977899; called by muse, mutect2, varscan2
- C3 | c.4299G>A p.E1433= | Silent (SNP) | VAF 64/246 reads (26%) | catalogued as rs1308694521, COSV55572972; called by muse, mutect2, varscan2
